Gene-level copy-number profile of tumor specimen C3N-00859-01 (profiled together with C3N-00859-02, C3N-00859-05) from CPTAC case C3N-00859, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIB; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.7 years (22,165 days).
Specimen C3N-00859-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e7977e9-4ec3-4e25-903b-95aefa6cfbd7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00859-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/72b79176-57d8-4a6d-a58c-0c948f69348f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 2: 51,369; copy number 3: 7,009; copy number 4: 13; copy number 5: 6.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,107,684–130,109,741, 2 genes (within-gene range 0–2): POTEF-AS1, RNU6-1049P.
- chr15:32,494,003–32,500,346, 1 gene: AC135983.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:32,398,956–32,455,634, 6 genes, copy number 5: AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
